Somatic mutation profile of tumor specimen TCGA-BP-4162-01A (aliquot TCGA-BP-4162-01A-02D-1386-10) from TCGA case TCGA-BP-4162, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.6 years (23,966 days).
Specimen TCGA-BP-4162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40a7452a-caa1-4650-aebe-8d52491c90f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4162-11A (Solid Tissue Normal), aliquot TCGA-BP-4162-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11ccb70b-0e99-43a0-a48f-5548a5e060db

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Frame Shift Del 5, Silent 5, Splice Site 2, Intron 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.2780C>G p.T927S | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.474); catalogued as COSV65072296; called by muse, mutect2, varscan2
- AVPR2 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs368306347, COSV61686969; called by muse, varscan2
- CASP7 | c.697A>T p.R233W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61883355; called by muse, mutect2, varscan2
- CDH12 | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV66447573; called by muse, mutect2, varscan2
- CUX1 | c.1764+1G>T p.X588_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | catalogued as COSV52946350; called by muse, mutect2, varscan2
- DCST1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV55063265, COSV55063820; called by muse, mutect2, varscan2
- DENND5A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs938418383, COSV60237853; called by muse, mutect2, varscan2
- EFCAB5 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759007679, COSV57937356; called by muse, mutect2, varscan2
- FAM200A | c.254T>A p.I85N | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68809066; called by muse, mutect2, varscan2
- FBLN2 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55490953; called by muse, mutect2, varscan2
- GCN1 | c.5077T>A p.F1693I | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56114748; called by muse, mutect2, varscan2
- GOLGB1 | c.1750A>G p.R584G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs1218377282, COSV61468499; called by muse, mutect2, varscan2
- HECTD4 | c.7505C>A p.P2502H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66399815; called by muse, mutect2, varscan2
- IL20RA | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); catalogued as COSV57360555; called by muse, mutect2
- ITGA6 | c.2660C>A p.T887K (on ENST00000442250; = p.T848K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs779823355, COSV51265046; called by muse, mutect2, varscan2
- KIF3B | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV65229332; called by muse, mutect2, varscan2
- MAGED2 | c.1209-2A>G p.X403_splice | Splice Site (SNP) | VAF 94/420 reads (22%) | catalogued as COSV54499377; called by muse, mutect2
- MYO18A | c.2686A>G p.T896A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV62873209; called by muse, mutect2, varscan2
- NRDE2 | c.2926_2929del p.S976Ffs*15 | Frame Shift Del (DEL) | VAF 45/235 reads (19%) | catalogued as rs1188543024; called by pindel, varscan2
- OR2T12 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV58779524; called by muse, mutect2, varscan2
- RPS26 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV56271596; called by muse, mutect2, varscan2
- RYR2 | c.6269G>A p.R2090Q | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1379845021, COSV63675160; called by muse, mutect2, varscan2
- SLC17A1 | c.33A>G p.K11= | Splice Region (SNP) | VAF 20/101 reads (20%) | catalogued as rs747924536, COSV55082252; called by muse, mutect2, varscan2
- TAF7L | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs925120787, COSV61258003; called by muse, mutect2, varscan2
- USP4 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55540556; called by muse, mutect2, varscan2
- ZIM3 | c.963T>A p.D321E | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.148); catalogued as COSV54146669; called by muse, mutect2, varscan2
- KIF3A | c.114_131delinsC p.V39Nfs*6 | Frame Shift Del (DEL) | VAF 130/493 reads (26%) | called by pindel, varscan2*
- POLB | c.75del p.F25Lfs*5 | Frame Shift Del (DEL) | VAF 44/187 reads (24%) | called by mutect2, varscan2
- RAP1A | c.380del p.G127Afs*8 | Frame Shift Del (DEL) | VAF 76/342 reads (22%) | called by mutect2, pindel, varscan2
- RDM1 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- YOD1 | c.435_439del p.L146Cfs*17 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- ZNF528 | c.609_611del p.N203_Q204delinsK | In Frame Del (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- C7orf31 | c.21G>A p.R7= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV52220122; called by muse, mutect2
- MYO3A | c.1533G>T p.L511= | Silent (SNP) | VAF 56/189 reads (30%) | catalogued as COSV56349385; called by muse, mutect2, varscan2
- TMEM251 | c.205C>T p.L69= (on ENST00000415050 / NM_001098621.4; = p.L37= on NM_015676.3) | Silent (SNP) | VAF 172/671 reads (26%) | catalogued as COSV52093529; called by muse, mutect2, varscan2
- ZCCHC13 | c.399C>T p.C133= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1176508239, COSV100272593, COSV59866657; called by muse, mutect2, varscan2
- ZNF350 | c.291G>C p.V97= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV54710594; called by muse, mutect2, varscan2
- CFAP94 | c.3+148C>G | Intron (SNP) | VAF 40/194 reads (21%) | catalogued as COSV57236775; called by muse, mutect2
- GRIA4 | c.1269+1344del | Intron (DEL) | VAF 4/15 reads (27%) | called by mutect2, pindel, varscan2
